Gene-level copy-number profile of tumor specimen TCGA-CN-4726-01A from TCGA case TCGA-CN-4726, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cheek mucosa; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 69.0 years (25,194 days).
Specimen TCGA-CN-4726-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.ac046d7c-465b-49cd-89de-bccdb347bec3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-4726-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8a6fd763-5718-4fb7-918e-f039eb4a664e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 8; copy number 2: 7,028; copy number 3: 2,376; copy number 4: 44,652; copy number 5: 1,391; copy number 6: 4,140; copy number 8: 29; copy number 11: 179; copy number 17: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-4726-01A-01D-1432-01): tumor purity 0.48, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 186 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:1,500,525–5,244,199, 102 genes, copy number 11–17 (broad region; genes not listed).
- chr12:5,315,961–5,319,347, 1 gene, copy number 11: AC006206.1.
- chr19:55,379,244–56,626,481, 81 genes, copy number 11 (broad region; genes not listed).
- chr19:56,643,159–56,671,783, 2 genes, copy number 11: SMIM17, ZNF835.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
